MMRF case MMRF_2176 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/11f59fe3-0fd2-450a-8a98-153c56c6d769

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.0 years (16,425 days); ISS stage: II; Days to last known disease status: 842 days (2.3 years); Days to last follow up: 842 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 0): M Protein 5.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.547 mg/dL; Immunoglobulin G 2.68 g/L; Immunoglobulin A 69.7 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 34 g/L; Total Protein 11.2 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 40 (ECOG 0): M Protein 1.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.733 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 3.99 g/L; Immunoglobulin A 19 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 658 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 29 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 124 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.646 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.888 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 4.58 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 250 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.946 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 3.22 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.12 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 391 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.134 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 3.27 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 510: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.924 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Glucose 5.45 mmol/L.
- Day 587 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.575 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 2.1 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 699 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.535 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.539 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 5.7 g/dL; Glucose 4.9 mmol/L.
- Day 758 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.734 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 842 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.076 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.121 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -26: Weight: 56 kg; Height: 161 cm.

Biospecimens (2 samples)
- Sample MMRF_2176_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_2176_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
